Somatic mutation profile of tumor specimen 627e6e36-3dca-4ee5-9755-6f3510 (aliquot 627e6e36-3dca-4ee5-9755-6f3510_D6) from CPTAC case 17OV002, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 627e6e36-3dca-4ee5-9755-6f3510: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1bf0f03-0867-4d98-b857-dc05385355c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen c0998304-329c-46ff-9678-616f3d (Blood Derived Normal), aliquot c0998304-329c-46ff-9678-616f3d_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69974ebc-ce66-40f7-a08d-3be34d71b408

The open-access MAF lists 9,196 somatic variants for this specimen: 6,510 protein-altering or splice-affecting, 1,595 silent, 1,091 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5,630, Silent 1,595, Nonsense Mutation 625, Intron 587, 3'UTR 179, RNA 149, Splice Site 126, Splice Region 87, 5'Flank 62, 5'UTR 58, 3'Flank 54, Frame Shift Ins 31.

Variants (750 of 9,196; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.2506C>T p.R836* | Nonsense Mutation (SNP) | VAF 126/311 reads (41%) | catalogued as rs72559722, CM001605, COSV56849386; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCL10 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 59/174 reads (34%) | catalogued as rs121918314, COSV65353611; ClinVar: pathogenic; called by muse, varscan2
- CACNA1A | c.5005C>T p.R1669* | Nonsense Mutation (SNP) | VAF 49/101 reads (49%) | catalogued as rs1555738369, CM101315, COSV64210783; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COCH | c.487C>T p.R163* (on ENST00000216361 / NM_001347720.1; = p.R98* on NM_004086.3) | Nonsense Mutation (SNP) | VAF 175/498 reads (35%) | catalogued as rs756790858, COSV53553071; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 26/110 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs139907646, COSV66705997; called by muse, varscan2
- DMD | c.2101G>T p.E701* | Nonsense Mutation (SNP) | VAF 129/312 reads (41%) | catalogued as rs1556780711; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH11 | c.5368G>T p.E1790* | Nonsense Mutation (SNP) | VAF 92/251 reads (37%) | catalogued as rs1164659091, COSV60954094; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMT3A | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as rs757823678, COSV53037113, COSV53081931; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- F9 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 84/211 reads (40%) | catalogued as rs137852248, CM940592, CM940593; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 82/211 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs869025203, CM1514549, COSV59538312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HDAC8 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | catalogued as rs886041936; ClinVar: pathogenic; called by muse, varscan2
- IL2RG | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 134/395 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs869320660, CM950693, COSV52149638; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 231/551 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs199472885, CM002297; ClinVar: not provided / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KIAA1109 | c.2902C>T p.R968C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1051597475, COSV52690863; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 136/415 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs104894365, CM061082, COSV55501342, COSV55883432; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- LMX1B | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 109/332 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs886039576, CM042391, COSV62742576; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MC2R | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 169/438 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs104894660, CM002358, COSV59617811; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYBPC3 | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs61897383, COSV99921126; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MYO7A | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 115/279 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs201539845, CD951791, CM110685; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 171/364 reads (47%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 36/88 reads (41%) | catalogued as rs1168400018; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PDK3 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as rs397515323, CM132388, COSV64792933; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 54/122 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.27); PolyPhen benign (0.221); catalogued as CM126689, COSV55903618; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 44/125 reads (35%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs1555791268, COSV59042459, COSV59042650; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 110/297 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554898067, CM1111457, COSV64291669, COSV64295080, COSV64295612; ClinVar: uncertain significance; called by muse, varscan2
- PTEN | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 116/262 reads (44%) | catalogued as rs786204934, CM110145, COSV64289396, COSV64297896; ClinVar: pathogenic; called by muse, varscan2
- SACS | c.10939G>T p.E3647* | Nonsense Mutation (SNP) | VAF 145/455 reads (32%) | catalogued as rs1156566314, COSV66538422, COSV66541147; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC16A1 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 247/621 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs606231302, CM1411342, COSV63710359; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 215/522 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60787768; called by muse, mutect2, varscan2
- SMARCB1 | c.992G>A p.R331H (on ENST00000263121; = p.R377H on NM_003073.5) | Missense Mutation (SNP) | VAF 48/283 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs387906812, CM122478, COSV51954090, COSV51954233, COSV51954740; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SYNE1 | c.9208C>T p.R3070* (on ENST00000367255 / NM_182961.4; = p.R3077* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 164/420 reads (39%) | catalogued as rs549779256, COSV54895674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TERT | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 205/600 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs1388515349, COSV57224146; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 228/601 reads (38%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRPM1 | c.2629C>T p.R877* | Nonsense Mutation (SNP) | VAF 144/410 reads (35%) | catalogued as rs1485132228, CM158240, COSV56637848; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TRPM1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 147/361 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs770561064, COSV56641594; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.85774C>T p.R28592* (on ENST00000591111; = p.R21168* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 101/258 reads (39%) | catalogued as rs1553539391, COSV60169898; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- UFM1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs1033946108, COSV53495720; ClinVar: pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 40/138 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68944577, COSV68946813; called by muse, mutect2, varscan2
- A2M | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1463177829, COSV59384882; called by muse, mutect2, varscan2
- A4GNT | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 92/238 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375267880; called by muse, mutect2, varscan2
- ABCA1 | c.5511G>T p.E1837D | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV66065097, COSV66071099; called by muse, mutect2, varscan2
- ABCA12 | c.5089G>A p.D1697N (on ENST00000272895 / NM_173076.3; = p.D1379N on NM_015657.3) | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.602); catalogued as rs1265616723, COSV55953217; called by muse, mutect2, varscan2
- ABCA12 | c.1211G>A p.R404Q (on ENST00000272895 / NM_173076.3; = p.R86Q on NM_015657.3) | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs752328328, COSV55961290, COSV99789386; called by muse, mutect2, varscan2
- ABCA12 | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as COSV55954315; called by muse, mutect2, varscan2
- ABCA13 | c.6793G>T p.E2265* | Nonsense Mutation (SNP) | VAF 45/114 reads (39%) | catalogued as COSV101330198; called by muse, mutect2, varscan2
- ABCA13 | c.9485G>A p.R3162Q | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369327461; called by muse, mutect2, varscan2
- ABCA13 | c.12288G>T p.K4096N | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV71287189; called by muse, mutect2, varscan2
- ABCA5 | c.3829G>T p.E1277* | Nonsense Mutation (SNP) | VAF 34/63 reads (54%) | catalogued as COSV67017767; called by muse, mutect2, varscan2
- ABCC2 | c.2731C>T p.R911* | Nonsense Mutation (SNP) | VAF 210/505 reads (42%) | catalogued as rs756825916, COSV64985495; called by muse, mutect2, varscan2
- ABCC5 | c.3990C>A p.F1330L | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as COSV55595876; called by muse, mutect2, varscan2
- ABCC9 | c.4408C>T p.L1470F | Missense Mutation (SNP) | VAF 167/437 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.248); catalogued as COSV53963987; called by muse, mutect2, varscan2
- ABCG5 | c.1552C>A p.L518I | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV53210706; called by muse, mutect2
- ABHD12 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 101/266 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs771187489; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABLIM3 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749211850, COSV58644631; called by muse, mutect2, varscan2
- ABRAXAS2 | c.105G>T p.E35D | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100045070; called by muse, mutect2, varscan2
- ABTB2 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs1313041239; called by muse, mutect2, varscan2
- AC004593.2 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 120/294 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs113586121; called by muse, mutect2, varscan2
- AC099489.1 | c.3276C>A p.F1092L | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.197); catalogued as COSV60862940; called by muse, mutect2, varscan2
- AC126283.2 | c.1409C>A p.S470Y | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV67100224; called by muse, mutect2, varscan2
- ACAD10 | c.1045C>A p.L349I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV58157433; called by muse, mutect2, varscan2
- ACADS | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 226/594 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs369167716; called by muse, mutect2, varscan2
- ACAP1 | c.2125G>T p.D709Y | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1165496909; called by muse, mutect2, varscan2
- ACAP2 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV100462881; called by muse, mutect2, varscan2
- ACAT1 | c.1006-8A>C | Splice Region (SNP) | VAF 59/200 reads (30%) | catalogued as rs368682208; called by muse, mutect2, varscan2
- ACIN1 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 105/289 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.174); catalogued as rs745432174, COSV52976144; called by muse, mutect2, varscan2
- ACLY | c.2956C>T p.R986* | Nonsense Mutation (SNP) | VAF 58/148 reads (39%) | catalogued as rs782631078, COSV59862901; called by muse, mutect2, varscan2
- ACLY | c.2504G>A p.R835H | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs868935385; called by muse, mutect2, varscan2
- ACLY | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV100709643; called by muse, mutect2, varscan2
- ACOT12 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56897277; called by muse, mutect2, varscan2
- ACP5 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as CM110716, COSV54537525; called by muse, mutect2
- ACP5 | c.390G>T p.W130C | Missense Mutation (SNP) | VAF 132/364 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54536491, COSV54536800; called by muse, mutect2, varscan2
- ACP7 | c.396G>A p.W132* | Nonsense Mutation (SNP) | VAF 38/98 reads (39%) | catalogued as rs766508010; called by muse, mutect2, varscan2
- ACP7 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs769646403, COSV58701383; called by muse, mutect2, varscan2
- ACRBP | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 92/254 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs377357185; called by muse, mutect2, varscan2
- ACSBG1 | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99357409; called by muse, mutect2, varscan2
- ACSL6 | c.1420G>A p.D474N (on ENST00000379240; = p.D499N on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs775219137, COSV57306564; called by muse, mutect2, varscan2
- ACSM2B | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.744); catalogued as COSV61658415; called by muse, mutect2, varscan2
- ACSM4 | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV68067432; called by muse, mutect2, varscan2
- ACSM4 | c.1345G>T p.D449Y | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV68067891, COSV68069762; called by mutect2, varscan2
- ACTL8 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 107/265 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs886522728, COSV64861479, COSV64862066; called by muse, mutect2, varscan2
- ACTL9 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as rs1555753378, COSV61004991; called by muse, mutect2, varscan2
- ACTR1B | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 42/628 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as rs1390360974, COSV56704939; called by muse, mutect2
- ACTR1B | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs755547378; called by muse, mutect2, varscan2
- ACTR3 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as rs1167208380; called by muse, mutect2, varscan2
- ACTRT1 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 27/386 reads (7%) | catalogued as COSV64419592; called by muse, mutect2
- ACTRT3 | c.493T>G p.F165V | Missense Mutation (SNP) | VAF 135/360 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100377349; called by muse, mutect2, varscan2
- ACVR1 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 138/345 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as rs772534199; called by muse, mutect2, varscan2
- ADAD1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs770989160, COSV56641414; called by muse, varscan2
- ADAM29 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537404539, COSV63660881; called by muse, mutect2, varscan2
- ADAM7 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs940085461, COSV51538068; called by muse, mutect2, varscan2
- ADAMTS16 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as rs779025729; called by muse, mutect2, varscan2
- ADAMTS20 | c.4295C>A p.S1432Y | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV67129159; called by muse, mutect2, varscan2
- ADAMTS20 | c.2449G>T p.E817* | Nonsense Mutation (SNP) | VAF 27/99 reads (27%) | catalogued as COSV67134539; called by muse, mutect2, varscan2
- ADAMTS5 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 101/259 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.835); catalogued as rs546124249, COSV53175804; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2527A>G p.T843A | Missense Mutation (SNP) | VAF 199/574 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.156); catalogued as rs780806985; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2737C>T p.R913C | Missense Mutation (SNP) | VAF 131/393 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs587652739, COSV55009166; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY1 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1182519617, COSV52029423; called by muse, mutect2, varscan2
- ADCY1 | c.2536G>A p.A846T | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338700641, COSV52040140; called by muse, mutect2, varscan2
- ADCY10 | c.2972C>A p.A991D | Missense Mutation (SNP) | VAF 151/394 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.118); catalogued as rs749117181; called by muse, mutect2, varscan2
- ADCY5 | c.3142G>A p.V1048M | Missense Mutation (SNP) | VAF 106/248 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1559779497; called by muse, mutect2, varscan2
- ADCY6 | c.2753C>T p.S918L | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs1484139082; called by muse, mutect2, varscan2
- ADCY8 | c.2465C>A p.S822Y | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV53910739; called by muse, mutect2, varscan2
- ADCY9 | c.1019G>T p.R340I | Missense Mutation (SNP) | VAF 152/460 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs780726526, COSV99569707; called by muse, mutect2, varscan2
- ADGB | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV100484148; called by muse, mutect2, varscan2
- ADGB | c.1454A>C p.K485T | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1477856417; called by muse, mutect2, varscan2
- ADGB | c.2029G>T p.D677Y | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58855494; called by muse, mutect2
- ADGRA1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as rs756895733, COSV66925851; called by muse, mutect2, varscan2
- ADGRA2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 66/248 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs777378349; called by muse, mutect2, varscan2
- ADGRA2 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373198805; called by muse, mutect2, varscan2
- ADGRB1 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60103648; called by muse, mutect2, varscan2
- ADGRB3 | c.3878A>G p.D1293G | Missense Mutation (SNP) | VAF 132/364 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs1351779059, COSV53262038; called by muse, mutect2, varscan2
- ADGRF3 | c.1567G>A p.D523N (on ENST00000311519 / NM_001145168.1; = p.D324N on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.275); catalogued as rs1236433003; called by muse, mutect2, varscan2
- ADGRG2 | c.320G>T p.R107I (on ENST00000379869 / NM_001079858.3; = p.R104I on NM_005756.4) | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.122); catalogued as COSV100492280, COSV100492436; called by muse, mutect2, varscan2
- ADGRG4 | c.1232C>A p.S411Y | Missense Mutation (SNP) | VAF 94/239 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV54958366; called by muse, mutect2, varscan2
- ADGRG4 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 96/258 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760044574, COSV54954779, COSV54961950; called by muse, mutect2, varscan2
- ADGRG4 | c.4925C>A p.P1642H | Missense Mutation (SNP) | VAF 118/314 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV99795130; called by muse, varscan2
- ADGRG4 | c.7647G>T p.K2549N | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1286224125, COSV54955324; called by muse, mutect2, varscan2
- ADGRL3 | c.1157G>A p.G386E (on ENST00000506720 / NM_001322402.2; = p.G318E on NM_015236.6) | Missense Mutation (SNP) | VAF 211/529 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72267540; called by muse, mutect2, varscan2
- ADGRL3 | c.4087G>A p.E1363K (on ENST00000506720 / NM_001322402.2; = p.E1252K on NM_015236.6) | Missense Mutation (SNP) | VAF 170/458 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.709); catalogued as rs762348569; called by muse, mutect2, varscan2
- ADGRL4 | c.1844C>A p.S615Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV66061720; called by muse, mutect2, varscan2
- ADGRL4 | c.443G>T p.R148I | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV100876627; called by muse, mutect2, varscan2
- ADGRV1 | c.6268C>T p.R2090C | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs1374306116; called by muse, mutect2, varscan2
- ADIPOR2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as rs200483941, COSV63946468; called by muse, mutect2, varscan2
- ADPRH | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780404094; called by muse, mutect2, varscan2
- ADRA2C | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356104647; called by muse, mutect2, varscan2
- AFAP1 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs766314353; called by muse, mutect2, varscan2
- AFAP1L1 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs573303164; called by muse, mutect2, varscan2
- AFF1 | c.847A>C p.S283R | Missense Mutation (SNP) | VAF 107/278 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100321009; called by muse, mutect2, varscan2
- AFF3 | c.2794-1G>T p.X932_splice | Splice Site (SNP) | VAF 33/108 reads (31%) | catalogued as COSV57864513; called by muse, mutect2, varscan2
- AFF3 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100418651, COSV100418770; called by mutect2, varscan2
- AFTPH | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs757559539; called by muse, mutect2, varscan2
- AGAP2 | c.1669C>T p.R557W (on ENST00000547588 / NM_001122772.2; = p.R221W on NM_014770.4) | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777644941; called by muse, mutect2, varscan2
- AGBL2 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs750247007, COSV54094493; called by muse, mutect2, varscan2
- AGGF1 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773668637; called by muse, mutect2, varscan2
- AGGF1 | c.2057G>A p.R686Q | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as rs1285675618, COSV57231249; called by muse, mutect2, varscan2
- AGL | c.1943C>A p.S648Y | Missense Mutation (SNP) | VAF 165/419 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54058203; called by muse, mutect2, varscan2
- AGO1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371043471; called by muse, mutect2, varscan2
- AGPAT2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 162/444 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs753285203; called by muse, mutect2, varscan2
- AGPAT4 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 117/303 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs369624936; called by muse, mutect2, varscan2
- AGRN | c.4429C>A p.L1477M | Missense Mutation (SNP) | VAF 154/454 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs757439560; called by muse, mutect2, varscan2
- AGTR1 | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 173/408 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV62558999; called by muse, mutect2, varscan2
- AHCTF1 | c.3083G>A p.R1028Q (on ENST00000366508; = p.R1002Q on NM_015446.5) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs757970163, COSV58249297; called by muse, mutect2, varscan2
- AHNAK | c.9574G>T p.D3192Y | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756170839; called by muse, mutect2, varscan2
- AHNAK | c.7288G>T p.E2430* | Nonsense Mutation (SNP) | VAF 32/98 reads (33%) | catalogued as COSV99945865; called by muse, varscan2
- AHNAK2 | c.17146G>A p.E5716K | Missense Mutation (SNP) | VAF 165/393 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.314); catalogued as rs373089411; called by muse, mutect2, varscan2
- AHRR | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338722288; called by muse, mutect2, varscan2
- AK7 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as rs746679886; called by muse, mutect2, varscan2
- AK9 | c.1417G>T p.E473* | Nonsense Mutation (SNP) | VAF 74/197 reads (38%) | catalogued as COSV58138852; called by muse, mutect2, varscan2
- AKAP11 | c.3716G>T p.R1239I | Missense Mutation (SNP) | VAF 75/222 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.329); catalogued as rs764701996, COSV50293062, COSV99214108; called by muse, mutect2, varscan2
- AKAP14 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100538446, COSV57630191; called by muse, mutect2, varscan2
- AKAP4 | c.904C>A p.L302I | Missense Mutation (SNP) | VAF 119/341 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV62073977; called by muse, mutect2, varscan2
- AKAP5 | c.419A>C p.N140T | Missense Mutation (SNP) | VAF 83/260 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs937849865; called by muse, mutect2, varscan2
- AKAP6 | c.3956T>G p.V1319G | Missense Mutation (SNP) | VAF 159/433 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV99798709; called by muse, mutect2, varscan2
- AKAP6 | c.6937C>T p.R2313* | Nonsense Mutation (SNP) | VAF 54/121 reads (45%) | catalogued as rs777113901, COSV55216486; called by muse, varscan2
- AKAP9 | c.5794C>T p.R1932* (on ENST00000359028; = p.R1900* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 85/199 reads (43%) | catalogued as rs978219635, COSV62354761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKIRIN1 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1444865140, COSV100881990; called by muse, mutect2, varscan2
- AKR1C4 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs142529153; called by muse, mutect2, varscan2
- AKT2 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as rs769806554, COSV100251889, COSV60909544; called by muse, mutect2, varscan2
- AKT3 | c.918C>A p.F306L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV99794565; called by muse, mutect2, varscan2
- AKT3 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 29/94 reads (31%) | catalogued as COSV55612501, COSV99796232; called by muse, mutect2, varscan2
- ALAS1 | c.1764G>A p.E588= | Splice Region (SNP) | VAF 42/115 reads (37%) | catalogued as COSV59627266; called by muse, mutect2, varscan2
- ALDH16A1 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs769307435; called by muse, mutect2, varscan2
- ALG14 | c.626C>A p.S209* | Nonsense Mutation (SNP) | VAF 85/250 reads (34%) | catalogued as COSV64636201; called by muse, mutect2, varscan2
- ALK | c.3638C>A p.P1213H | Missense Mutation (SNP) | VAF 142/352 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66576589; called by muse, mutect2, varscan2
- ALK | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.597); catalogued as rs775302364, COSV66555883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALKBH2 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | catalogued as COSV57450339; called by muse, mutect2, varscan2
- ALMS1 | c.9359A>C p.K3120T | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs375038066; ClinVar: uncertain significance; called by muse, varscan2
- ALPK2 | c.4758G>T p.Q1586H | Missense Mutation (SNP) | VAF 132/308 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV64496537; called by muse, mutect2, varscan2
- AMZ1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs371888865; called by muse, mutect2, varscan2
- ANAPC1 | c.1157C>A p.S386Y | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100595056; called by mutect2, varscan2
- ANK3 | c.1769C>A p.S590Y | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV55052742; called by mutect2, varscan2
- ANKAR | c.3275G>T p.R1092I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.367); catalogued as COSV55614188; called by muse, mutect2, varscan2
- ANKAR | c.4070G>A p.R1357Q | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1376221117, COSV51461865; called by muse, mutect2, varscan2
- ANKEF1 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 101/252 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs1440335644, COSV65692535; called by muse, mutect2, varscan2
- ANKFY1 | c.3278G>A p.R1093Q (on ENST00000341657 / NM_001330063.2; = p.R1094Q on NM_016376.5) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV58917541; called by muse, mutect2, varscan2
- ANKK1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs541172883, CM1414172, COSV100393091; called by muse, mutect2, varscan2
- ANKLE2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 121/386 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1483776717; called by muse, mutect2, varscan2
- ANKRD1 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 67/526 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs367609929; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD13C | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV52033096, COSV52035472; called by muse, mutect2, varscan2
- ANKRD26 | c.2573G>A p.R858Q | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.561); catalogued as rs999645398; called by muse, mutect2, varscan2
- ANKRD26 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.563); catalogued as COSV63091812; called by muse, mutect2
- ANKRD30B | c.1620G>T p.K540N | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780460113, COSV62818716; called by muse, mutect2, varscan2
- ANKRD30B | c.2523G>T p.Q841H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.183); catalogued as COSV57702796; called by muse, mutect2, varscan2
- ANKRD31 | c.4714G>A p.D1572N | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV57159771; called by muse, mutect2, varscan2
- ANKRD36 | c.4952C>A p.S1651Y | Missense Mutation (SNP) | VAF 79/434 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100825824; called by muse, mutect2, varscan2
- ANKRD50 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 171/451 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.311); catalogued as COSV72385743, COSV72385826; called by muse, mutect2, varscan2
- ANKRD53 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 108/256 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.79); catalogued as COSV99721212; called by muse, mutect2, varscan2
- ANKS1A | c.2120C>T p.S707L | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as rs1412567042; called by muse, mutect2, varscan2
- ANKS6 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747073459, COSV62050205, COSV62052560; called by muse, mutect2, varscan2
- ANKS6 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as rs376656982; called by muse, mutect2, varscan2
- ANLN | c.1999C>T p.R667C | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs761217773; called by muse, varscan2
- ANO4 | c.2276C>A p.P759H (on ENST00000392977 / NM_001286615.2; = p.P724H on NM_178826.4) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202462618, COSV54614445; called by muse, mutect2, varscan2
- ANO4 | c.2708C>T p.S903L (on ENST00000392977 / NM_001286615.2; = p.S868L on NM_178826.4) | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV54587306; called by muse, mutect2, varscan2
- ANO4 | c.2857G>A p.E953K (on ENST00000392977 / NM_001286615.2; = p.E918K on NM_178826.4) | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs1566286837; called by muse, mutect2, varscan2
- ANOS1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 144/415 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.687); catalogued as rs1205589697, COSV52916553; called by muse, mutect2, varscan2
- ANXA6 | c.1481C>A p.S494Y | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1358406784; called by muse, mutect2
- ANXA8 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 54/464 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1255805570; called by muse, mutect2, varscan2
- AP2A2 | c.708C>T p.I236= | Splice Region (SNP) | VAF 57/140 reads (41%) | catalogued as rs765985458, COSV59957921; called by muse, mutect2, varscan2
- AP5M1 | c.1059C>A p.F353L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs766342082; called by muse, mutect2, varscan2
- APBA3 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs548949116, COSV57462096; called by muse, mutect2, varscan2
- APCDD1 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 122/298 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV62373246; called by mutect2, varscan2
- APLP2 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776642613, COSV53838788; called by muse, mutect2, varscan2
- APOB | c.12698C>T p.S4233L | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs377125320, COSV51925242; called by muse, mutect2, varscan2
- APOB | c.11607C>A p.F3869L | Missense Mutation (SNP) | VAF 181/445 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.065); catalogued as COSV51942607, COSV51954942; called by muse, varscan2
- APOOL | c.159T>G p.Y53* | Nonsense Mutation (SNP) | VAF 60/166 reads (36%) | catalogued as rs1182125747; called by muse, mutect2, varscan2
- AQR | c.3202C>A p.L1068M | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50042509; called by muse, mutect2, varscan2
- AR | c.2518G>A p.D840N | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1419690127, COSV65955958, COSV65965297; called by muse, mutect2
- ARAP3 | c.2959C>T p.L987F | Missense Mutation (SNP) | VAF 132/356 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53350653; called by muse, mutect2, varscan2
- ARAP3 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 87/196 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs778112171; called by muse, mutect2, varscan2
- AREL1 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748168958, COSV62666394; called by muse, mutect2, varscan2
- AREL1 | c.356A>C p.Q119P | Missense Mutation (SNP) | VAF 94/246 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.461); catalogued as rs1418861797; called by muse, mutect2, varscan2
- ARFGEF1 | c.2107G>T p.E703* | Nonsense Mutation (SNP) | VAF 116/286 reads (41%) | catalogued as COSV99141048, COSV99144661; called by muse, varscan2
- ARFGEF3 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 119/305 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs374061664; called by muse, mutect2, varscan2
- ARHGAP1 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100357887; called by muse, mutect2, varscan2
- ARHGAP17 | c.671G>T p.R224I | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99252805; called by muse, mutect2, varscan2
- ARHGAP18 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs564963735; called by muse, mutect2, varscan2
- ARHGAP20 | c.3335C>A p.S1112Y | Missense Mutation (SNP) | VAF 131/343 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV99505326; called by muse, mutect2, varscan2
- ARHGAP29 | c.2837G>A p.R946Q | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs370625624; called by muse, mutect2, varscan2
- ARHGAP35 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV68334483; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 95/227 reads (42%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGAP44 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as rs768572384, COSV52402867; called by muse, mutect2, varscan2
- ARHGAP45 | c.2775G>T p.M925I | Missense Mutation (SNP) | VAF 187/451 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53123595; called by muse, mutect2, varscan2
- ARHGEF1 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); catalogued as rs781934892; called by muse, mutect2, varscan2
- ARHGEF15 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs771433483, COSV62724589; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF19 | c.623C>A p.S208Y | Missense Mutation (SNP) | VAF 132/308 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs1381875665; called by mutect2, varscan2
- ARHGEF2 | c.725-1G>T p.X242_splice (on ENST00000361247 / NM_001162383.2; = p.X214_splice on NM_004723.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 54/144 reads (38%) | catalogued as COSV58118166; called by muse, varscan2
- ARHGEF26 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754708272, COSV62843732; called by muse, mutect2, varscan2
- ARHGEF6 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 41/328 reads (13%) | catalogued as COSV51689821; called by muse, mutect2, varscan2
- ARID1A | c.605C>A p.S202Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV61386706; called by muse, mutect2, varscan2
- ARID1A | c.2974G>T p.E992* | Nonsense Mutation (SNP) | VAF 41/100 reads (41%) | catalogued as COSV61372304; called by muse, mutect2, varscan2
- ARID4B | c.3175C>T p.R1059* | Nonsense Mutation (SNP) | VAF 117/312 reads (38%) | catalogued as COSV51599070, COSV51599207; called by muse, mutect2, varscan2
- ARID5B | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 90/230 reads (39%) | catalogued as COSV54422475; called by muse, mutect2, varscan2
- ARMC12 | c.260G>A p.S87N (on ENST00000373866 / NM_001286574.2; = p.S114N on NM_145028.5) | Missense Mutation (SNP) | VAF 102/277 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs1056152201; called by muse, varscan2
- ARMCX5 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs947710517, COSV55766684; called by muse, mutect2
- ARMCX5 | c.1571C>A p.S524* | Nonsense Mutation (SNP) | VAF 39/133 reads (29%) | catalogued as COSV55767528; called by muse, mutect2, varscan2
- ARNTL2 | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 66/188 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99038826; called by mutect2, varscan2
- ARPC3 | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); catalogued as rs766604518; called by muse, mutect2, varscan2
- ARPP21 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV51792546; called by muse, varscan2
- ARPP21 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV51803252; called by muse, mutect2, varscan2
- ARRB1 | c.619-1G>T p.X207_splice | Splice Site (SNP) | VAF 15/60 reads (25%) | catalogued as COSV63575037; called by muse, mutect2, varscan2
- ARRDC3 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 100/266 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99475229, COSV99475257; called by mutect2, varscan2
- ARSB | c.719C>A p.S240Y | Missense Mutation (SNP) | VAF 159/412 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as CM074044; called by muse, mutect2, varscan2
- ARSI | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 108/292 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746240121, COSV60816590; called by muse, mutect2, varscan2
- ARSK | c.1385C>A p.S462Y | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.324); catalogued as COSV66170448; called by muse, mutect2, varscan2
- ART1 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as rs767619916, COSV51703995; called by muse, mutect2, varscan2
- ARX | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 136/352 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.081); catalogued as rs1387480394; called by muse, mutect2, varscan2
- ASAH2 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 67/202 reads (33%) | catalogued as rs1413048671; called by muse, mutect2, varscan2
- ASB13 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as rs202037153; called by muse, mutect2, varscan2
- ASIC2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 81/406 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs749146881, COSV63293686; called by muse, varscan2
- ASIC4 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 214/556 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs749947411; called by muse, mutect2, varscan2
- ASMT | c.910C>A p.L304I (on ENST00000381229; = p.L332I on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/570 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201741679; called by mutect2, varscan2
- ASPA | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 22/345 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV99279067; called by muse, mutect2
- ASPA | c.295T>G p.L99V | Missense Mutation (SNP) | VAF 125/286 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV99559312; called by muse, mutect2, varscan2
- ASPM | c.8564G>T p.R2855I | Missense Mutation (SNP) | VAF 160/426 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV54135001; called by mutect2, varscan2
- ASPSCR1 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.689); catalogued as rs777946155, COSV60730884; called by muse, mutect2, varscan2
- ASTN1 | c.2701C>T p.R901W | Missense Mutation (SNP) | VAF 134/408 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as rs777093050, COSV62504008; called by muse, mutect2
- ASTN2 | c.2326G>T p.E776* (on ENST00000313400 / NM_001365069.1; = p.E725* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 74/186 reads (40%) | catalogued as COSV100526444; called by muse, mutect2, varscan2
- ASXL1 | c.1517G>T p.R506I | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1464693264; called by muse, mutect2, varscan2
- ASXL2 | c.1119C>A p.F373L | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55454869, COSV55462123; called by muse, mutect2
- ASZ1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as rs868189125, COSV52912602, COSV52912960; called by muse, mutect2, varscan2
- ATAD3A | c.1359-1G>A p.X453_splice | Splice Site (SNP) | VAF 51/160 reads (32%) | catalogued as COSV100186428; called by muse, mutect2, varscan2
- ATG14 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 178/404 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs747592425; called by muse, mutect2, varscan2
- ATG14 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs560262834; called by muse, mutect2, varscan2
- ATMIN | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 124/274 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs778646077; called by muse, mutect2, varscan2
- ATP10A | c.1123A>C p.I375L | Missense Mutation (SNP) | VAF 104/237 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV63513722; called by muse, mutect2, varscan2
- ATP11A | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1443017095, COSV52108983; called by muse, mutect2, varscan2
- ATP11B | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.709); catalogued as COSV60026701; called by muse, mutect2, varscan2
- ATP12A | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs370861260; called by muse, mutect2, varscan2
- ATP13A1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.021); catalogued as rs1200247290, COSV52289730; called by muse, mutect2, varscan2
- ATP13A2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 133/368 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs1323958366, COSV58701713; called by muse, mutect2, varscan2
- ATP1A1 | c.2828C>T p.S943L | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55192266; called by muse, mutect2, varscan2
- ATP1A2 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 140/365 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as rs765021457, COSV63403673; called by muse, mutect2, varscan2
- ATP1A4 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs750851195, COSV63625375; called by muse, varscan2
- ATP2A1 | c.2502C>A p.F834L | Missense Mutation (SNP) | VAF 97/246 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV62869468; called by mutect2, varscan2
- ATP2A2 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 154/393 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs767974635; called by muse, mutect2, varscan2
- ATP2B1 | c.2230C>T p.R744* | Nonsense Mutation (SNP) | VAF 38/88 reads (43%) | catalogued as rs902976276, COSV53809982; called by muse, varscan2
- ATP5F1B | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as rs1461296669; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 171/449 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs148307049; called by muse, mutect2, varscan2
- ATP6V1B2 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.662); catalogued as rs1321960568; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs577956380, COSV99369247; called by muse, mutect2, varscan2
- ATP6V1E1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs144829775, COSV99494214; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8B1 | c.2089G>T p.D697Y | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs762857853, COSV52173943; called by muse, mutect2, varscan2
- ATP8B2 | c.598G>T p.E200* (on ENST00000672630; = p.E167* on NM_001005855.2) | Nonsense Mutation (SNP) | VAF 36/120 reads (30%) | catalogued as COSV59246261; called by muse, mutect2, varscan2
- ATR | c.2905G>T p.E969* | Nonsense Mutation (SNP) | VAF 73/261 reads (28%) | catalogued as COSV63386308; called by muse, mutect2, varscan2
- ATRAID | c.666G>T p.E222D (on ENST00000611786; = p.E109D on NM_016085.5) | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV104391635, COSV53025675; called by muse, mutect2, varscan2
- ATRNL1 | c.3805C>T p.R1269* | Nonsense Mutation (SNP) | VAF 41/112 reads (37%) | catalogued as rs1555060449, COSV104410951, COSV58116748; called by muse, mutect2
- ATRX | c.5773G>A p.D1925N | Missense Mutation (SNP) | VAF 98/254 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1157154167, COSV64881281; called by muse, mutect2, varscan2
- ATRX | c.3835G>A p.E1279K | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100970278; called by muse, mutect2
- ATRX | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 136/383 reads (36%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV64872363; called by muse, mutect2, varscan2
- ATXN3 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 42/126 reads (33%) | catalogued as COSV61494145; called by muse, mutect2, varscan2
- ATXN7L3 | c.734C>T p.S245L (on ENST00000389384 / NM_001382309.1; = p.S252L on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1217484794; called by muse, mutect2, varscan2
- AURKA | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 103/263 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs779964295, COSV57170369; called by muse, mutect2, varscan2
- AUTS2 | c.3130C>T p.R1044C | Missense Mutation (SNP) | VAF 109/324 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs768420169, COSV61398967; called by muse, mutect2, varscan2
- AVEN | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60736120; called by muse, mutect2, varscan2
- AXDND1 | c.2647C>T p.R883* | Nonsense Mutation (SNP) | VAF 41/111 reads (37%) | catalogued as rs761897633, COSV62640876, COSV62646075; called by muse, mutect2, varscan2
- AXL | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as rs753706427, COSV56567403; called by muse, mutect2, varscan2
- B3GALT1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 99/233 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.633); catalogued as rs1340830027; called by muse, mutect2, varscan2
- B3GNT6 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV62828256; called by muse, mutect2, varscan2
- BAAT | c.1037G>T p.R346I | Missense Mutation (SNP) | VAF 277/745 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV52289374; called by muse, mutect2, varscan2
- BACH2 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs1346571372, COSV57591784; called by muse, mutect2, varscan2
- BANK1 | c.401G>T p.R134I | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.325); catalogued as rs1387081923, COSV100536923; called by muse, mutect2
- BARD1 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.212); catalogued as rs876658741, COSV53611116; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ1A | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.381); catalogued as rs138917569; called by mutect2, varscan2
- BAZ1B | c.2807G>A p.R936Q | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs1159927298; called by muse, mutect2, varscan2
- BAZ2B | c.1583G>A p.S528N | Missense Mutation (SNP) | VAF 178/425 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs748908183; called by muse, mutect2, varscan2
- BAZ2B | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs537143287, COSV58611117; called by muse, mutect2, varscan2
- BAZ2B | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.968); catalogued as rs768136268; called by muse, mutect2, varscan2
- BBS2 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 179/435 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs1199632846; called by muse, mutect2, varscan2
- BBX | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 63/155 reads (41%) | catalogued as COSV57883835; called by muse, mutect2, varscan2
- BCAN | c.1752G>T p.E584D | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.883); catalogued as rs142167508; called by muse, mutect2, varscan2
- BCAR3 | c.2399G>T p.R800I | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53077075; called by muse, mutect2, varscan2
- BCAS1 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs539868796, COSV65086779; called by muse, mutect2, varscan2
- BCAS3 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs775428400, COSV66774910; called by muse, mutect2, varscan2
- BCAS3 | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.979); catalogued as rs767082124; called by muse, mutect2, varscan2
- BCAS3 | c.2726G>A p.R909Q (on ENST00000390652 / NM_001353144.2; = p.R894Q on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs776735306; called by muse, mutect2, varscan2
- BCHE | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 46/132 reads (35%) | catalogued as rs534912670, COSV52253705; called by muse, mutect2, varscan2
- BCL10 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65353458; called by muse, varscan2
- BCL10 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1268648553; called by muse, mutect2
- BCL11B | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 95/263 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV61734782; called by muse, mutect2, varscan2
- BCL9 | c.2155G>T p.D719Y | Missense Mutation (SNP) | VAF 117/320 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99325593; called by muse, mutect2, varscan2
- BCL9 | c.3848G>T p.R1283I | Missense Mutation (SNP) | VAF 174/438 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52345168; called by muse, mutect2, varscan2
- BCLAF1 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.87); catalogued as rs765643189; called by muse, mutect2
- BCLAF3 | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as COSV61413018; called by muse, mutect2, varscan2
- BCO2 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 85/178 reads (48%) | catalogued as rs780599024, COSV99737550; called by muse, mutect2, varscan2
- BCORL1 | c.5093G>A p.R1698Q | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.94); PolyPhen benign (0.066); catalogued as rs756266434; called by muse, mutect2, varscan2
- BCR | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 115/272 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs767559039; called by muse, mutect2, varscan2
- BDKRB2 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.424); catalogued as rs924868565; called by muse, mutect2, varscan2
- BDP1 | c.7666C>T p.R2556* | Nonsense Mutation (SNP) | VAF 76/271 reads (28%) | catalogued as rs746088956, COSV62432459; called by muse, mutect2, varscan2
- BECN1 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs775164058; called by muse, mutect2, varscan2
- BEND4 | c.1513C>T p.H505Y | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.622); catalogued as rs1311552113; called by muse, mutect2, varscan2
- BGN | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 106/263 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); catalogued as COSV100525175, COSV59035987; called by muse, mutect2, varscan2
- BHMT | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV57153540; called by muse, mutect2, varscan2
- BICC1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs776915414; called by muse, mutect2, varscan2
- BICC1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1035741792, COSV65857705; called by muse, mutect2, varscan2
- BICC1 | c.1451C>A p.P484H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99570351; called by muse, mutect2, varscan2
- BIN2 | c.345G>T p.E115D | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV57204657, COSV57205326; called by muse, mutect2, varscan2
- BIRC6 | c.9368G>T p.R3123I | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV70205922; called by muse, mutect2, varscan2
- BIRC6 | c.13408G>T p.E4470* | Nonsense Mutation (SNP) | VAF 28/71 reads (39%) | catalogued as COSV101428288; called by muse, mutect2, varscan2
- BIRC7 | c.880C>T p.R294C (on ENST00000217169 / NM_139317.3; = p.R276C on NM_022161.4) | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs776089365; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99958434; called by muse, varscan2
- BIVM-ERCC5 | c.3198G>T p.E1066D | Missense Mutation (SNP) | VAF 23/331 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV63244296; called by muse, mutect2
- BLNK | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.839); catalogued as rs781854815; called by muse, mutect2, varscan2
- BMP2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs776834114, COSV66577307; called by muse, mutect2, varscan2
- BMP5 | c.1211C>A p.T404N | Missense Mutation (SNP) | VAF 92/260 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63705018; called by mutect2, varscan2
- BMP5 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 20/133 reads (15%) | catalogued as COSV63706517; called by muse, mutect2, varscan2
- BMT2 | c.929T>G p.F310C | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.649); catalogued as rs771111613, COSV51780488; called by muse, mutect2, varscan2
- BMT2 | c.264A>C p.K88N | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV51774917; called by muse, mutect2, varscan2
- BOD1L1 | c.5465C>T p.S1822L | Missense Mutation (SNP) | VAF 129/315 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs771167771, COSV99239039; called by muse, mutect2, varscan2
- BOP1 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 131/356 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1261173428; called by muse, mutect2, varscan2
- BPIFC | c.1149C>T p.F383= | Splice Region (SNP) | VAF 56/121 reads (46%) | catalogued as rs200868839, COSV55910552; called by muse, mutect2, varscan2
- BRCA1 | c.3334G>T p.E1112* | Nonsense Mutation (SNP) | VAF 170/446 reads (38%) | catalogued as CD961838, COSV104398344; called by mutect2, varscan2
- BRCA2 | c.4743G>T p.E1581D | Missense Mutation (SNP) | VAF 92/252 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as COSV66463335; called by muse, mutect2, varscan2
- BRD1 | c.3037G>A p.E1013K (on ENST00000216267 / NM_001349940.1; = p.E1144K on NM_001304808.3) | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1046139158, COSV53462584; called by muse, mutect2, varscan2
- BRD2 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 94/205 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs764147069; called by muse, varscan2
- BRDT | c.1359G>T p.E453D | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV100746172; called by muse, mutect2, varscan2
- BRF1 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780380442; called by muse, mutect2, varscan2
- BRMS1L | c.167G>T p.R56I | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104370973, COSV53763758; called by muse, varscan2
- BRWD3 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 57/403 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1315684063; called by muse, mutect2, varscan2
- BRWD3 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs1236574829, COSV64745626; called by muse, mutect2, varscan2
- BSN | c.9013C>A p.L3005I | Missense Mutation (SNP) | VAF 147/380 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as COSV56524834; called by muse, mutect2, varscan2
- BST1 | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs778121703; called by muse, mutect2, varscan2
- BST1 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.113); catalogued as rs113632818, COSV53945345; called by muse, mutect2, varscan2
- BTAF1 | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 101/222 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs992826231, COSV99794822; called by muse, mutect2, varscan2
- BTAF1 | c.3184G>A p.D1062N | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs758122724, COSV99795913; called by muse, mutect2, varscan2
- BTBD19 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.356); catalogued as rs1252917084, COSV59499789; called by muse, mutect2, varscan2
- BTBD7 | c.1307C>A p.S436* | Nonsense Mutation (SNP) | VAF 135/366 reads (37%) | catalogued as COSV58283320; called by muse, mutect2, varscan2
- BTK | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs782740486; called by muse, mutect2
- BTN3A2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs774256825, COSV62686837; called by muse, mutect2, varscan2
- BTN3A3 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 79/231 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs551526423; called by muse, mutect2, varscan2
- BTNL8 | c.774C>A p.F258L | Missense Mutation (SNP) | VAF 113/329 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs779292643, COSV51461594; called by muse, mutect2, varscan2
- BTRC | c.473C>T p.S158F (on ENST00000370187 / NM_033637.4; = p.S122F on NM_003939.5) | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV64563715; called by muse, mutect2, varscan2
- BUB1 | c.2959G>A p.D987N | Missense Mutation (SNP) | VAF 114/285 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418232388, COSV57062953; called by muse, mutect2, varscan2
- BUB1 | c.2958C>T p.I986= | Splice Region (SNP) | VAF 115/283 reads (41%) | catalogued as rs148368189; called by muse, mutect2, varscan2
- BUB1 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs975621280, COSV57063381; called by muse, mutect2, varscan2
- BUD13 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs903586401; called by muse, mutect2, varscan2
- C10orf105 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as rs745887522; called by muse, mutect2, varscan2
- C10orf71 | c.873G>T p.K291N | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV60507981; called by muse, mutect2
- C12orf50 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 87/265 reads (33%) | catalogued as rs200677856, COSV53893431, COSV53897104; called by muse, mutect2, varscan2
- C14orf119 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 119/349 reads (34%) | catalogued as rs375745222; called by muse, mutect2, varscan2
- C16orf96 | c.2818C>T p.R940W | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1017590510; called by muse, mutect2, varscan2
- C17orf80 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 134/350 reads (38%) | catalogued as rs377133509; called by muse, mutect2, varscan2
- C17orf97 | c.1128G>T p.E376D | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.134); catalogued as rs1296562640, COSV64076412; called by muse, varscan2
- C19orf57 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1015748913, COSV60970064; called by muse, mutect2, varscan2
- C1QTNF9B | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 60/299 reads (20%) | catalogued as rs749779965; called by muse, mutect2, varscan2
- C1S | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 163/437 reads (37%) | catalogued as COSV61070546; called by muse, mutect2, varscan2
- C1orf127 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs12069017; called by muse, mutect2, varscan2
- C1orf167 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1258584035; called by muse, mutect2, varscan2
- C1orf87 | c.737C>A p.S246Y | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.178); catalogued as COSV100967009; called by muse, mutect2, varscan2
- C20orf194 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 34/112 reads (30%) | catalogued as COSV52700848; called by muse, mutect2, varscan2
- C2CD2L | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs1367071845; called by muse, mutect2
- C2CD4B | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 73/159 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.08); catalogued as rs1375531236, COSV66791137; called by muse, mutect2, varscan2
- C2CD6 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 58/140 reads (41%) | catalogued as rs748210926, COSV53792214; called by muse, varscan2
- C2orf16 | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 104/259 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV68645335; called by muse, mutect2, varscan2
- C2orf16 | c.3119G>T p.R1040I | Missense Mutation (SNP) | VAF 116/304 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV62673728; called by muse, mutect2, varscan2
- C2orf16 | c.5083C>T p.R1695C | Missense Mutation (SNP) | VAF 80/347 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs761163522; called by muse, varscan2
- C2orf50 | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs368973410; called by muse, mutect2, varscan2
- C2orf74 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV67041445; called by muse, mutect2, varscan2
- C2orf74 | c.479G>T p.R160I | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101283007; called by muse, mutect2, varscan2
- C3orf38 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 94/290 reads (32%) | catalogued as rs1348452549, COSV59627599; called by muse, varscan2
- C4orf47 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); catalogued as COSV100294188; called by muse, mutect2, varscan2
- C4orf54 | c.2828C>T p.A943V | Missense Mutation (SNP) | VAF 170/460 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs967066685; called by muse, mutect2, varscan2
- C5 | c.3940G>A p.D1314N | Missense Mutation (SNP) | VAF 125/337 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs771283592; called by muse, mutect2, varscan2
- C5 | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767119237; called by muse, mutect2, varscan2
- C5orf52 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs1280984901, COSV69625751; called by muse, mutect2, varscan2
- C6 | c.2574G>T p.K858N | Missense Mutation (SNP) | VAF 148/402 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); catalogued as COSV54710299; called by muse, mutect2, varscan2
- C6orf163 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1244387542, COSV100851119; called by muse, mutect2, varscan2
- C6orf58 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs757715087, COSV61667039, COSV61667266; called by muse, mutect2, varscan2
- C7orf25 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 110/270 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1003393016, COSV63273458; called by muse, mutect2, varscan2
- C7orf57 | c.839A>G p.Q280R | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.044); catalogued as rs1337131003; called by muse, mutect2, varscan2
- C8A | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 164/454 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV63483242; called by muse, mutect2, varscan2
- C8orf74 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 95/276 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV58755524; called by muse, mutect2, varscan2
- CA10 | c.137-1G>A p.X46_splice | Splice Site (SNP) | VAF 12/98 reads (12%) | catalogued as COSV53345040; called by muse, mutect2, varscan2
- CA5A | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs200681449, COSV59238863; called by muse, mutect2, varscan2
- CABIN1 | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 216/526 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372869082; called by muse, mutect2, varscan2
- CABIN1 | c.5065G>A p.D1689N | Missense Mutation (SNP) | VAF 86/217 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs199949467, COSV54079159; called by muse, mutect2, varscan2
- CABP2 | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV53709112; called by muse, mutect2, varscan2
- CACHD1 | c.3562C>T p.R1188* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as COSV51561160; called by muse, mutect2, varscan2
- CACNA1B | c.4222G>A p.V1408I | Missense Mutation (SNP) | VAF 188/504 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs776836911; called by muse, mutect2, varscan2
- CACNA1C | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 124/313 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV59696193; called by muse, mutect2, varscan2
- CACNA1E | c.4323G>T p.K1441N | Missense Mutation (SNP) | VAF 89/213 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756231898; called by muse, mutect2, varscan2
- CACNA1F | c.5363G>A p.R1788H | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs868978376, COSV59903379; called by muse, mutect2, varscan2
- CACNA1G | c.4116G>T p.K1372N | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61732663; called by muse, mutect2, varscan2
- CACNA2D1 | c.1297C>A p.P433T | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV62379795; called by muse, mutect2, varscan2
- CADPS2 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373213538; called by muse, mutect2, varscan2
- CALCOCO2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs765125675, COSV104386233, COSV51952812; called by muse, mutect2, varscan2
- CAMK1G | c.891G>T p.K297N | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs187124482, COSV50520297; called by muse, mutect2, varscan2
- CAMKMT | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as rs759924384, COSV101034655; called by muse, mutect2, varscan2
- CAMLG | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 70/174 reads (40%) | catalogued as rs1255711307, COSV51804357; called by muse, varscan2
- CAMTA1 | c.2840C>T p.S947L | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs113652510, COSV100349428; called by muse, mutect2, varscan2
- CAMTA2 | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100742001; called by muse, mutect2, varscan2
- CAND2 | c.213C>T p.C71= | Splice Region (SNP) | VAF 19/64 reads (30%) | catalogued as rs1054069122; called by muse, mutect2, varscan2
- CANX | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.886); catalogued as rs148961304; called by muse, mutect2, varscan2
- CAPN12 | c.1684G>T p.E562* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as COSV99400668; called by muse, mutect2, varscan2
- CAPN13 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV54436132; called by muse, mutect2, varscan2
- CAPN14 | c.1996G>T p.D666Y | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV67292002; called by muse, mutect2, varscan2
- CAPN9 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT tolerated (0.9); PolyPhen benign (0.183); catalogued as rs750960558, COSV55232886; called by muse, mutect2, varscan2
- CAPZB | c.690G>T p.E230D | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.183); catalogued as COSV104384672; called by muse, mutect2, varscan2
- CARD6 | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 158/379 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as rs779331588; called by muse, mutect2, varscan2
- CASD1 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51971469; called by muse, varscan2
- CASP5 | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52827895; called by muse, mutect2, varscan2
- CASP8 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 69/201 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV51847255, COSV51849187; called by muse, mutect2, varscan2
- CASQ2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 148/401 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121434549, CM013693, COSV54770079; called by muse, mutect2, varscan2
- CATSPERB | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs139686935; called by muse, mutect2, varscan2
- CAV3 | c.289T>G p.F97V | Missense Mutation (SNP) | VAF 105/283 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1232546000, COSV57479109; called by muse, mutect2, varscan2
- CBFA2T2 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs267605890, COSV100656440, COSV60073320; called by muse, mutect2, varscan2
- CBL | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 154/440 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755244263, COSV50633583; called by muse, mutect2, varscan2
- CBR4 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.231); catalogued as COSV60369713; called by muse, mutect2, varscan2
- CBWD6 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 31/136 reads (23%) | catalogued as rs1368646032; called by muse, mutect2, varscan2
- CBX1 | c.135C>A p.F45L | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV56682209; called by muse, mutect2, varscan2
- CCDC127 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 130/361 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs983986680, COSV57256768; called by muse, mutect2, varscan2
- CCDC141 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs760619402, COSV99837314; called by muse, mutect2, varscan2
- CCDC141 | c.1530G>T p.E510D | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.238); catalogued as rs1051369128; called by muse, mutect2, varscan2
- CCDC144A | c.1618G>T p.E540* | Nonsense Mutation (SNP) | VAF 63/164 reads (38%) | catalogued as COSV60698076; called by mutect2, varscan2
- CCDC168 | c.17597C>T p.S5866L | Missense Mutation (SNP) | VAF 111/306 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1444656839; called by muse, mutect2, varscan2
- CCDC168 | c.14159G>T p.R4720I | Missense Mutation (SNP) | VAF 98/328 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); catalogued as COSV99079836; called by muse, mutect2, varscan2
- CCDC172 | c.144G>T p.E48D | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.52); catalogued as COSV60936745; called by muse, mutect2, varscan2
- CCDC181 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 74/212 reads (35%) | catalogued as rs766836009, COSV63158080; called by muse, mutect2, varscan2
- CCDC190 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 106/233 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs1312017712, COSV63363236; called by muse, mutect2, varscan2
- CCDC191 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs778514406, COSV55670023; called by muse, mutect2, varscan2
- CCDC28A | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV60425627; called by muse, mutect2, varscan2
- CCDC30 | c.530G>A p.R177Q (on ENST00000340612; = p.R134Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs771159252, COSV59605287; called by muse, mutect2, varscan2
- CCDC33 | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.404); catalogued as COSV58358024; called by muse, mutect2, varscan2
- CCDC70 | c.509A>C p.K170T | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs1243662270; called by muse, mutect2, varscan2
- CCDC74A | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 37/126 reads (29%) | catalogued as rs777987967, COSV54605146; called by muse, mutect2, varscan2
- CCDC77 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs189099875; called by muse, mutect2, varscan2
- CCDC80 | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 135/367 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774845090, COSV99245016; called by muse, mutect2, varscan2
- CCDC82 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 45/121 reads (37%) | catalogued as COSV53595946, COSV99567275; called by muse, mutect2, varscan2
- CCDC93 | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100098641; called by muse, mutect2, varscan2
- CCDC93 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs754008225, COSV100098692; called by muse, mutect2, varscan2
- CCDC96 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 120/340 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as COSV59508132; called by muse, mutect2, varscan2
- CCER1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62645768; called by muse, mutect2, varscan2
- CCHCR1 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 149/420 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs369082621; called by muse, mutect2, varscan2
- CCM2 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 134/381 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as CD033699; called by muse, mutect2, varscan2
- CCNG1 | c.254C>A p.S85Y | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100546697; called by muse, mutect2, varscan2
- CCNL1 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.05); catalogued as rs771814832, COSV55820663; called by muse, mutect2, varscan2
- CD276 | c.810C>A p.F270L | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59205370; called by mutect2, varscan2
- CD300E | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 123/409 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs1250703050, COSV60791455; called by muse, mutect2, varscan2
- CD300LG | c.845C>T p.T282M | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs1433903655, COSV99517571; called by muse, mutect2, varscan2
- CD320 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 125/347 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); catalogued as rs188158114; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD33 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV99220603; called by muse, mutect2, varscan2
- CD4 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs782149774; called by muse, varscan2
- CD40 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 172/433 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs1406703700; called by muse, mutect2, varscan2
- CD68 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 89/240 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV51511198; called by muse, mutect2, varscan2
- CDC14A | c.1477G>T p.D493Y | Missense Mutation (SNP) | VAF 109/268 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV60559449; called by muse, mutect2, varscan2
- CDC14C | c.1489G>A p.D497N (on ENST00000428251; = p.D390N on NM_152627.3) | Missense Mutation (SNP) | VAF 99/750 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs765363567; called by muse, varscan2
- CDC20B | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as rs765031404, COSV99697314; called by mutect2, varscan2
- CDC20B | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV57056405; called by muse, varscan2
- CDC27 | c.802T>G p.L268V | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1166244554; called by muse, mutect2, varscan2
- CDC42BPA | c.5195C>T p.P1732L (on ENST00000334218 / NM_001366019.2; = p.P1719L on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1286539810; called by muse, mutect2, varscan2
- CDC42BPG | c.3256G>A p.D1086N | Missense Mutation (SNP) | VAF 109/319 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750041105; called by muse, mutect2, varscan2
- CDH1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 190/537 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs121964873, COSV55736787, COSV55737055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH10 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 33/71 reads (46%) | catalogued as COSV52598264; called by muse, varscan2
- CDH10 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.148); catalogued as rs369925572, COSV100051837; called by muse, mutect2, varscan2
- CDH12 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 103/261 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.878); catalogued as rs371285182; called by muse, mutect2, varscan2
- CDH13 | c.1273T>G p.S425A | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV51788486; called by muse, mutect2, varscan2
- CDH17 | c.1574C>A p.A525D | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV99217584; called by muse, mutect2
- CDH19 | c.1908G>T p.E636D | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.741); catalogued as rs1365141706, COSV100051150; called by muse, varscan2
- CDH19 | c.1876C>A p.L626I | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.681); catalogued as rs1413928670, COSV100051227, COSV50959575; called by muse, varscan2
- CDH2 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs150313483; called by muse, mutect2, varscan2
- CDH23 | c.1619G>A p.G540D | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs746480906; called by muse, mutect2, varscan2
- CDH26 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 79/172 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs780399754; called by muse, mutect2, varscan2
- CDH5 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1259309540; called by muse, mutect2, varscan2
- CDH6 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 16/111 reads (14%) | catalogued as rs769326582, COSV54067130; called by muse, mutect2, varscan2
- CDH7 | c.1217C>A p.S406Y | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.534); catalogued as rs548755121, COSV59881315, COSV59885942; called by muse, mutect2, varscan2
- CDHR2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs781138032, COSV56134419; called by muse, mutect2, varscan2
- CDHR3 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs376253605; called by muse, mutect2, varscan2
- CDK17 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774240202, COSV54131222; called by muse, mutect2, varscan2
- CDK5 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763930713, COSV52525428; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 163/427 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs752327431, COSV62571777; called by muse, mutect2, varscan2
- CDK5RAP3 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 155/424 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748985064; called by muse, mutect2, varscan2
- CDK6 | c.863G>T p.R288I | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56008526; called by muse, mutect2, varscan2
- CDKL5 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 105/268 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.913); catalogued as rs765304446; called by muse, mutect2, varscan2
- CDRT1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 129/329 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1327139893, COSV63052386, COSV63054528; called by muse, mutect2, varscan2
- CDSN | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 142/377 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs750259125, COSV99456754; called by muse, mutect2, varscan2
- CDX2 | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1326821235, COSV66829434; called by muse, mutect2, varscan2
- CDYL | c.244C>T p.R82W (on ENST00000328908 / NM_001368125.1; = p.R28W on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59358793; called by muse, mutect2, varscan2
- CELA2A | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.301); catalogued as rs1227939841, COSV100657623; called by muse, mutect2, varscan2
- CELF4 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs769180157, COSV58452460; called by muse, mutect2, varscan2
- CELSR2 | c.3856G>A p.E1286K | Missense Mutation (SNP) | VAF 163/423 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs768192595; called by muse, mutect2, varscan2
- CEMIP2 | c.3208C>T p.R1070* | Nonsense Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as COSV65484514; called by muse, mutect2, varscan2
- CENATAC | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57723889, COSV57723919; called by mutect2, varscan2
- CENPE | c.7670C>A p.S2557Y | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.854); catalogued as COSV54391095, COSV99476964; called by muse, mutect2, varscan2
- CENPE | c.3613C>A p.L1205I | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV99477134; called by muse, mutect2, varscan2
- CENPF | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65276789; called by muse, mutect2, varscan2
- CENPF | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as rs978773209, COSV100871883; called by muse, mutect2, varscan2
- CENPF | c.4216G>A p.E1406K | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs766232547, COSV65273075; called by muse, mutect2, varscan2
- CENPF | c.9281G>A p.R3094Q | Missense Mutation (SNP) | VAF 145/351 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs569821438; called by muse, mutect2, varscan2
- CEP120 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); catalogued as COSV60267199; called by muse, mutect2, varscan2
- CEP128 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs778415802, COSV55369147; called by muse, mutect2, varscan2
- CEP135 | c.3154C>A p.H1052N | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV99954770; called by mutect2, varscan2
- CEP164 | c.2809G>T p.D937Y | Missense Mutation (SNP) | VAF 100/279 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54040725; called by muse, mutect2, varscan2
- CEP250 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as rs756430899, COSV61168341; called by mutect2, varscan2
- CEP290 | c.1254G>T p.E418D | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as rs763556203, COSV100469680; called by muse, mutect2, varscan2
- CEP85 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.231); catalogued as rs972436888, COSV53329019; called by muse, mutect2, varscan2
- CEP85L | c.2230C>A p.L744I | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV100874370; called by muse, mutect2, varscan2
- CER1 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 132/322 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101097738; called by muse, mutect2, varscan2
- CERKL | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as rs757547517; called by muse, mutect2, varscan2
- CERKL | c.338G>T p.R113I | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV100184211; called by muse, mutect2
- CERT1 | c.637C>T p.R213* (on ENST00000405807 / NM_001130105.1; = p.R85* on NM_005713.3) | Nonsense Mutation (SNP) | VAF 49/135 reads (36%) | catalogued as rs866447504; called by muse, mutect2, varscan2
- CES2 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 131/386 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781527420, COSV57696338; called by muse, mutect2, varscan2
- CETN3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV99300658; called by muse, mutect2, varscan2
- CFAP100 | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV61504495; called by mutect2, varscan2
- CFAP100 | c.988C>A p.L330M | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as COSV61502825; called by muse, mutect2, varscan2
- CFAP221 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs552536625, COSV54656355; called by muse, mutect2, varscan2
- CFAP251 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 83/122 reads (68%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs200006803; called by muse, mutect2, varscan2
- CFAP251 | c.1208A>G p.N403S | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs758923741; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.1090C>A p.L364I | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.738); catalogued as rs760491203, COSV100291914; called by mutect2, varscan2
- CFAP36 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as rs1268160460; called by muse, mutect2, varscan2
- CFAP46 | c.7437C>A p.F2479L | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54158341; called by muse, mutect2, varscan2
- CFAP46 | c.3572C>T p.S1191L | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs575250325; called by muse, mutect2, varscan2
- CFAP54 | c.6664G>T p.E2222* | Nonsense Mutation (SNP) | VAF 42/123 reads (34%) | catalogued as COSV61575928; called by muse, mutect2, varscan2
- CFAP58 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs775995835, COSV100459016; called by muse, mutect2, varscan2
- CFAP92 | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as COSV54047012; called by muse, mutect2, varscan2
- CFH | c.2728G>T p.E910* | Nonsense Mutation (SNP) | VAF 126/280 reads (45%) | catalogued as COSV66407260; called by muse, varscan2
- CFHR3 | c.574T>C p.C192R | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1260299819; called by muse, mutect2, varscan2
- CFTR | c.812C>A p.S271Y | Missense Mutation (SNP) | VAF 124/400 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99134396; called by muse, mutect2, varscan2
- CFTR | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs369040061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGNL1 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs777219860; called by muse, mutect2, varscan2
- CHCHD5 | c.310-8C>A | Splice Region (SNP) | VAF 52/148 reads (35%) | catalogued as rs775233413, COSV100260811; called by muse, mutect2, varscan2
- CHD4 | c.2335C>T p.R779W (on ENST00000357008 / NM_001363606.2; = p.R792W on NM_001273.5) | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58901404; called by muse, mutect2, varscan2
- CHD8 | c.5422C>T p.R1808* (on ENST00000646647 / NM_001170629.2; = p.R1529* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 54/116 reads (47%) | catalogued as rs1555313519, COSV63037485; called by muse, mutect2, varscan2
- CHD8 | c.5323C>T p.R1775W (on ENST00000646647 / NM_001170629.2; = p.R1496W on NM_020920.4) | Missense Mutation (SNP) | VAF 132/389 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs536360321; called by muse, mutect2, varscan2
- CHD8 | c.3068C>T p.A1023V (on ENST00000646647 / NM_001170629.2; = p.A744V on NM_020920.4) | Missense Mutation (SNP) | VAF 103/263 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV67869649; called by muse, mutect2, varscan2
- CHIA | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 129/297 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs752677743, COSV58474195; called by muse, mutect2, varscan2
- CHRAC1 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs1045148605; called by muse, mutect2, varscan2
- CHRD | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs267599715; called by muse, mutect2, varscan2
- CHRM2 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 228/595 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.313); catalogued as rs774760812, COSV100280682; called by muse, mutect2, varscan2
- CHRM2 | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.285); catalogued as COSV57779831, COSV57785393; called by muse, mutect2, varscan2
- CHRNA1 | c.394C>T p.R132C (on ENST00000261007 / NM_001039523.3; = p.R107C on NM_000079.4) | Missense Mutation (SNP) | VAF 138/384 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs140268343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNA9 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs759080788; called by muse, mutect2, varscan2
- CHRNB2 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 251/698 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769249583, COSV63808511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNB4 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 168/345 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.336); catalogued as rs143402850; called by muse, mutect2, varscan2
- CHST14 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 164/479 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.292); catalogued as rs369563820; called by muse, mutect2, varscan2
- CHST15 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 134/345 reads (39%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.732); catalogued as rs750731230, COSV100655103; called by muse, mutect2, varscan2
- CHST5 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 134/354 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444039409; called by muse, mutect2, varscan2
- CHST8 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 91/232 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs780352841, COSV52859548; called by muse, mutect2, varscan2
- CHST9 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 94/219 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779465790, COSV52434903, COSV52443413; called by muse, varscan2
- CHSY3 | c.1817C>A p.S606Y | Missense Mutation (SNP) | VAF 90/249 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); catalogued as COSV100519257, COSV59288434; called by muse, mutect2, varscan2
- CHSY3 | c.2636G>A p.R879Q | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as rs777029388, COSV59282136; called by muse, mutect2, varscan2
- CHTOP | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs375961912, COSV64155479; called by muse, mutect2, varscan2
- CHUK | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 94/254 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs200519611, COSV100957288; called by muse, mutect2, varscan2
- CHUK | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 123/352 reads (35%) | catalogued as rs769592752, COSV64918782; called by muse, mutect2, varscan2
- CHUK | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 70/189 reads (37%) | catalogued as rs373590755; called by muse, mutect2, varscan2
- CIITA | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 211/597 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as rs140269818; called by muse, mutect2, varscan2
- CLASP1 | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 90/239 reads (38%) | catalogued as COSV55313295; called by muse, mutect2, varscan2
- CLASP1 | c.3895G>A p.D1299N | Missense Mutation (SNP) | VAF 105/299 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs896630387; called by muse, mutect2, varscan2
- CLCA4 | c.641C>A p.S214Y | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV55367727; called by muse, mutect2, varscan2
- CLCN1 | c.2902G>A p.D968N | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs748630375, COSV100577719; called by muse, mutect2, varscan2
- CLCN3 | c.2191C>T p.R731W | Missense Mutation (SNP) | VAF 114/267 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV100641737; called by muse, mutect2, varscan2
- CLDN10 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV54823618; called by muse, mutect2, varscan2
- CLEC2B | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.19); catalogued as rs377198013; called by muse, mutect2, varscan2
- CLEC3A | c.36G>T p.K12N (on ENST00000651443; = p.K3N on NM_005752.6) | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.381); catalogued as COSV55219969; called by muse, varscan2
- CLEC3A | c.117G>T p.R39S (on ENST00000651443; = p.R30S on NM_005752.6) | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs545876028, COSV55221128; called by muse, varscan2
- CLHC1 | c.1312C>A p.L438I | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68463870; called by muse, mutect2
- CLK2 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 175/487 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs764316833; called by muse, mutect2, varscan2
- CLK3 | c.1147G>A p.A383T (on ENST00000395066 / NM_001130028.1; = p.A235T on NM_003992.4) | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as rs763864813, COSV59339878, COSV59341042; called by muse, varscan2
- CLK4 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as rs1352568347, COSV60318282; called by muse, mutect2, varscan2
- CLRN1 | c.585C>A p.C195* | Nonsense Mutation (SNP) | VAF 66/184 reads (36%) | catalogued as COSV55806277; called by muse, mutect2, varscan2
- CLRN1 | c.310T>G p.F104V (on ENST00000327047 / NM_174878.3; = p.F28V on NM_052995.2) | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1275617847; called by muse, mutect2
- CLSTN1 | c.538G>A p.D180N (on ENST00000377298 / NM_001009566.3; = p.D170N on NM_014944.4) | Missense Mutation (SNP) | VAF 109/270 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.419); catalogued as rs760081150; called by muse, mutect2, varscan2
- CLTC | c.3799C>T p.R1267C | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1351855076, COSV52244881; called by muse, mutect2, varscan2
- CLUAP1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs1011011156; called by muse, mutect2, varscan2
- CMAS | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1470744717, COSV57556509; called by muse, mutect2, varscan2
- CMPK2 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 38/262 reads (15%) | catalogued as COSV56776223; called by mutect2, varscan2
- CMTM2 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.867); catalogued as COSV51748872; called by muse, mutect2
- CMYA5 | c.1269G>T p.K423N | Missense Mutation (SNP) | VAF 97/260 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV71407485; called by muse, mutect2, varscan2
- CNBD1 | c.1157G>A p.R386K | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73074095; called by muse, mutect2, varscan2
- CNGA1 | c.1793T>A p.I598N | Missense Mutation (SNP) | VAF 34/568 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV62053119; called by muse, mutect2
- CNGA2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs1391435408; called by muse, mutect2, varscan2
- CNGA2 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374694060, COSV100323687; called by muse, mutect2, varscan2
- CNGB1 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 33/418 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51900886; called by muse, mutect2
- CNOT1 | c.6787C>T p.R2263C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54700022; called by muse, mutect2, varscan2
- CNOT1 | c.6560G>A p.R2187Q | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs867725873, COSV55321408; called by muse, mutect2, varscan2
- CNTFR | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV100667501; called by muse, mutect2, varscan2
- CNTN1 | c.118G>T p.G40* | Nonsense Mutation (SNP) | VAF 71/169 reads (42%) | catalogued as COSV61641588, COSV61645745; called by mutect2, varscan2
- CNTN4 | c.1916C>T p.S639F | Missense Mutation (SNP) | VAF 165/467 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV61873437; called by muse, mutect2, varscan2
- CNTNAP3 | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 47/660 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1427108514, COSV52665237; called by muse, mutect2
- CNTNAP5 | c.3700C>T p.R1234* | Nonsense Mutation (SNP) | VAF 82/229 reads (36%) | catalogued as rs982218609, COSV70474001, COSV70477179; called by muse, varscan2
- COBL | c.3569C>T p.S1190L | Missense Mutation (SNP) | VAF 82/215 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs140576062; called by muse, mutect2, varscan2
- COCH | c.1094C>A p.S365Y (on ENST00000216361 / NM_001347720.1; = p.S300Y on NM_004086.3) | Missense Mutation (SNP) | VAF 62/396 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757456469, COSV53551911; called by mutect2, varscan2
- COG1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 237/659 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as rs763005617, COSV55430824; called by muse, mutect2, varscan2
- COG1 | c.1556C>A p.S519Y | Missense Mutation (SNP) | VAF 249/686 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as rs764231325; called by muse, mutect2, varscan2
- COG2 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 38/111 reads (34%) | catalogued as COSV64186392; called by muse, mutect2, varscan2
- COL11A1 | c.3227G>A p.R1076H | Missense Mutation (SNP) | VAF 88/243 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs148464130; called by muse, mutect2, varscan2
- COL12A1 | c.8813G>A p.R2938H | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs752206319, COSV59396582; called by muse, mutect2, varscan2
- COL12A1 | c.4810G>T p.E1604* | Nonsense Mutation (SNP) | VAF 57/153 reads (37%) | catalogued as COSV100486462; called by muse, mutect2, varscan2
- COL17A1 | c.2432C>T p.S811L | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs145101288; called by muse, mutect2, varscan2
- COL20A1 | c.2079C>A p.I693= | Splice Region (SNP) | VAF 60/193 reads (31%) | catalogued as COSV100491630; called by mutect2, varscan2
- COL21A1 | c.476G>T p.R159I | Missense Mutation (SNP) | VAF 112/296 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99780563; called by mutect2, varscan2
- COL22A1 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 99/242 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs774502960; called by muse, mutect2, varscan2
- COL27A1 | c.5382G>T p.Q1794H | Missense Mutation (SNP) | VAF 102/301 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV61922800; called by muse, mutect2, varscan2
- COL4A6 | c.449T>G p.L150R | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.425); catalogued as COSV100563808; called by muse, mutect2, varscan2
- COL5A3 | c.5122G>A p.E1708K | Missense Mutation (SNP) | VAF 95/261 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs563109290, COSV53409530; called by muse, mutect2, varscan2
- COL6A1 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs771207889; called by muse, mutect2, varscan2
- COL6A2 | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 188/408 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.657); catalogued as rs200709432, COSV56019223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.1792G>A p.D598N | Missense Mutation (SNP) | VAF 216/654 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as rs778400474, COSV55078994; called by muse, mutect2, varscan2
- COL6A5 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs1466294050, COSV55195465; called by muse, mutect2, varscan2
- COL6A5 | c.6916G>T p.E2306* (on ENST00000312481; = p.E2302* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 90/249 reads (36%) | catalogued as rs1398587398, COSV99592516; called by muse, mutect2, varscan2
- COL7A1 | c.4485C>T p.G1495= | Splice Region (SNP) | VAF 154/367 reads (42%) | catalogued as rs367958901; called by muse, mutect2, varscan2
- COL9A1 | c.17A>C p.K6T | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV61828442; called by muse, mutect2, varscan2
- COL9A3 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs776652428; called by muse, mutect2, varscan2
- COLEC10 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 139/348 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773596648, COSV60520914; called by muse, mutect2, varscan2
- COPA | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767740500, COSV54097954; called by muse, mutect2, varscan2
- COPS7A | c.656C>A p.T219N | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV57526498, COSV99976548; called by muse, mutect2, varscan2
- COQ8B | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs199930495; called by muse, mutect2, varscan2
- CORIN | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 81/215 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs757102291, COSV56688730; called by muse, mutect2, varscan2
- CORIN | c.2402G>T p.R801M | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99903121; called by muse, mutect2, varscan2
- CORO1A | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 150/359 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV54632029; called by muse, mutect2, varscan2
- CORO1B | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 130/364 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs769428845, COSV58167759; called by muse, mutect2, varscan2
- CORO2A | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779898610, COSV59662906; called by muse, mutect2, varscan2
- CORO2B | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1418170409, COSV55953578; called by muse, mutect2, varscan2
- CPD | c.2795G>A p.R932Q | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.943); catalogued as rs1319078793; called by muse, mutect2, varscan2
- CPED1 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs187314481, COSV60000351; called by muse, mutect2, varscan2
- CPED1 | c.2836C>A p.L946I | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100120367, COSV59997549; called by muse, mutect2, varscan2
- CPM | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as rs765708241; called by muse, mutect2, varscan2
- CPNE4 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV70190052; called by muse, mutect2, varscan2
- CPNE6 | c.426C>T p.I142= | Splice Region (SNP) | VAF 15/47 reads (32%) | catalogued as COSV53743632; called by muse, mutect2, varscan2
- CPOX | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 86/225 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs200810233, COSV51639995; called by muse, mutect2, varscan2
- CPT1C | c.142-1G>A p.X48_splice | Splice Site (SNP) | VAF 80/202 reads (40%) | catalogued as COSV54918121; called by muse, mutect2, varscan2
- CPT1C | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as rs753309074, COSV54918161; called by muse, mutect2, varscan2
- CPXM1 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760853354; called by muse, mutect2, varscan2
- CRAMP1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51964956; called by muse, mutect2, varscan2
- CRB1 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 153/404 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs369775002, COSV66328542; called by muse, mutect2, varscan2
- CRB2 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.293); catalogued as COSV100749636; called by muse, mutect2, varscan2
- CRBN | c.1218A>C p.K406N | Missense Mutation (SNP) | VAF 136/374 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.395); catalogued as COSV51640061; called by muse, mutect2, varscan2
- CREBBP | c.4317C>A p.F1439L | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52125814; called by mutect2, varscan2
- CROCC | c.4579G>A p.E1527K | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as rs769419747, COSV100978128; called by muse, mutect2, varscan2
- CRTC3 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs773913638, COSV51597573; called by muse, varscan2
- CRTC3 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 161/428 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs563914760, COSV51595888; called by muse, mutect2, varscan2
- CRYAB | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 178/434 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139750142, CM116555, COSV99909868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRYBB1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 101/308 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1400757152, COSV53232441; called by muse, mutect2, varscan2
- CRYBG1 | c.2671C>A p.Q891K | Missense Mutation (SNP) | VAF 108/246 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV64810429, COSV64811068; called by mutect2, varscan2
- CSDE1 | c.1647C>A p.F549L (on ENST00000358528 / NM_001007553.3; = p.F518L on NM_007158.6) | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.786); catalogued as COSV54741178; called by muse, mutect2, varscan2
- CSMD1 | c.5137C>A p.L1713M (on ENST00000520002; = p.L1712M on NM_033225.6) | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV59340382; called by muse, mutect2, varscan2
- CSMD2 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 106/291 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs759006019, COSV53905731; called by muse, mutect2, varscan2
- CSMD3 | c.3061C>T p.R1021C (on ENST00000297405 / NM_001363185.1; = p.R917C on NM_052900.3) | Missense Mutation (SNP) | VAF 99/256 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52339290; called by muse, mutect2, varscan2
- CSMD3 | c.2362C>A p.L788I (on ENST00000297405 / NM_001363185.1; = p.L684I on NM_052900.3) | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs1225316618, COSV52188167; called by muse, mutect2, varscan2
- CSNK1G2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.698); catalogued as rs750798326; called by muse, mutect2, varscan2
- CSPG4 | c.4066G>A p.A1356T | Missense Mutation (SNP) | VAF 94/266 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs750753426; called by muse, mutect2, varscan2
- CSPP1 | c.554G>A p.R185H (on ENST00000676605; = p.R144H on NM_024790.6) | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1386679081; called by muse, mutect2, varscan2
- CSRP3 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 190/532 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs753711278, COSV56390064; called by muse, mutect2, varscan2
- CST8 | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 120/366 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.054); catalogued as COSV55672182; called by muse, varscan2
- CTAG2 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 119/373 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1557241905; called by muse, mutect2, varscan2
- CTAGE1 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.078); catalogued as COSV66942991; called by muse, mutect2, varscan2
- CTAGE15 | c.1170C>A p.F390L | Missense Mutation (SNP) | VAF 117/606 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101372159; called by muse, mutect2, varscan2
- CTBP2 | c.357C>T p.L119= | Splice Region (SNP) | VAF 42/94 reads (45%) | catalogued as rs111629462; called by muse, mutect2, varscan2
- CTCF | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50467714; called by muse, mutect2, varscan2
- CTCF | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.623); catalogued as COSV50490739; called by muse, mutect2, varscan2
- CTDNEP1 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs1157664900; called by muse, mutect2, varscan2
- CTHRC1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 191/518 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs141428810, COSV99042792; called by muse, mutect2, varscan2
- CTNNA1 | c.2689C>A p.L897I | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100241950; called by muse, mutect2, varscan2
- CTSH | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs1236795859, COSV54985286; called by muse, mutect2, varscan2
- CTSO | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as rs376990374; called by muse, mutect2, varscan2
- CTTNBP2 | c.2677C>T p.P893S | Missense Mutation (SNP) | VAF 140/343 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1366968093; called by muse, mutect2, varscan2
- CUL4B | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 109/274 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100341059; called by muse, mutect2, varscan2
- CUL5 | c.860G>A p.R287K | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs139693510; called by muse, mutect2, varscan2
- CUL7 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 114/291 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as rs369208421; called by muse, mutect2, varscan2
- CUL9 | c.5248C>T p.R1750W | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755020493; called by muse, mutect2, varscan2
- CUTC | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 122/314 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762189565, COSV65081642; called by muse, mutect2, varscan2
- CWC15 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs1555095301, COSV99688423; called by muse, mutect2, varscan2
- CWF19L2 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as COSV56508888; called by muse, mutect2, varscan2
- CXCL13 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as rs1413304928; called by muse, mutect2, varscan2
- CXCR1 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 90/547 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.818); catalogued as COSV99826334; called by muse, mutect2, varscan2
- CXCR2 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 134/331 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs201754155, COSV59282517; called by muse, mutect2, varscan2
- CYBB | c.942G>T p.K314N | Missense Mutation (SNP) | VAF 216/577 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV101059768; called by muse, mutect2, varscan2
- CYFIP2 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as COSV59050054; called by muse, mutect2, varscan2
- CYLC2 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV66337849; called by muse, mutect2, varscan2
- CYP11A1 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 242/612 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs900306752, COSV51432965; called by muse, varscan2
- CYP11B1 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 216/592 reads (36%) | catalogued as COSV52830210; called by mutect2, varscan2
- CYP26B1 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 215/547 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs752223643, COSV50010601; called by muse, mutect2, varscan2
- CYP2C18 | c.1284C>A p.F428L | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53674753; called by muse, mutect2, varscan2
- CYP2S1 | c.1446C>A p.F482L | Missense Mutation (SNP) | VAF 136/411 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.138); catalogued as COSV59506234; called by mutect2, varscan2
- CYP46A1 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201296209, COSV55893072; called by muse, mutect2, varscan2
- CYP4B1 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767511721, COSV54723491; called by muse, mutect2, varscan2
- CYP4V2 | c.215-1G>T p.X72_splice | Splice Site (SNP) | VAF 106/301 reads (35%) | catalogued as CS114007, COSV101114753; called by muse, mutect2, varscan2
- CYP4V2 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as rs894863416, COSV66505057; called by muse, mutect2, varscan2
- CYP7A1 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 121/289 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs1210055982, COSV56963769, COSV56964129; called by muse, mutect2, varscan2
- CYP7A1 | c.335G>T p.R112I | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as COSV56965740; called by mutect2, varscan2
- CYP7B1 | c.878C>A p.S293Y | Missense Mutation (SNP) | VAF 50/564 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59587968; called by muse, mutect2
- CYRIA | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs756679332, COSV62866194; called by muse, mutect2, varscan2
- DAGLB | c.255T>G p.I85M | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770295650; called by mutect2, varscan2
- DAPK1 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs772431146, COSV63788568, COSV63788808; called by muse, mutect2, varscan2
- DAPK2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 153/379 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1403509203, COSV56048960; called by muse, mutect2, varscan2
- DAPK3 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 111/290 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1184011576, COSV56664675; called by muse, mutect2, varscan2
- DBNL | c.1185G>T p.E395D (on ENST00000448521 / NM_001014436.3; = p.E396D on NM_014063.7) | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV51977593; called by muse, mutect2, varscan2
- DCAF8L2 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as rs1266440439; called by muse, mutect2, varscan2
- DCC | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 166/436 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59087430, COSV59097183; called by muse, mutect2, varscan2
- DCC | c.3389G>T p.R1130I | Missense Mutation (SNP) | VAF 170/450 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV71439804, COSV71442724; called by muse, mutect2, varscan2
- DCDC1 | c.4156C>T p.R1386C (on ENST00000597505 / NM_001367979.1; = p.R493C on NM_020869.3) | Missense Mutation (SNP) | VAF 108/320 reads (34%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.555); catalogued as rs201587746, COSV58000770; called by muse, mutect2, varscan2
- DCDC1 | c.2513C>A p.S838Y | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.906); catalogued as COSV100664174; called by muse, mutect2, varscan2
- DCDC2 | c.1320A>C p.Q440H | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs763616532; called by muse, varscan2
- DCHS1 | c.4657C>T p.R1553C | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.744); catalogued as COSV100202202; called by muse, mutect2, varscan2
- DCK | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs370045223; called by muse, mutect2, varscan2
- DCLK1 | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV55198488; called by muse, mutect2, varscan2
- DCPS | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs773359297, COSV55010758; called by muse, mutect2, varscan2
- DCPS | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs776570838, COSV55012337; called by muse, mutect2, varscan2
- DCTN4 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781129875, COSV69781873; called by muse, mutect2, varscan2
- DCUN1D1 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 26/46 reads (57%) | catalogued as COSV53045920; called by muse, mutect2, varscan2
- DDX24 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348543022; called by muse, mutect2, varscan2
- DDX24 | c.1061A>G p.N354S | Missense Mutation (SNP) | VAF 180/435 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs1208346259; called by muse, mutect2, varscan2
- DDX3X | c.929G>A p.R310Q (on ENST00000399959; = p.R311Q on NM_001356.5) | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV67863096; called by muse, mutect2, varscan2
- DDX3X | c.1805G>A p.R602Q (on ENST00000399959; = p.R603Q on NM_001356.5) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101302338; called by muse, mutect2, varscan2
- DDX58 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.311); catalogued as rs765663574, COSV101152650; called by muse, mutect2, varscan2
- DDX60 | c.2266G>T p.D756Y | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101190396; called by muse, mutect2, varscan2
- DEFB104A | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.031); catalogued as rs763043014, COSV58629877; called by mutect2, varscan2
- DEFB129 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 111/229 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.275); catalogued as COSV55732042; called by muse, mutect2, varscan2
- DENND11 | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV101530703; called by muse, mutect2, varscan2
- DENND2A | c.521C>A p.S174* | Nonsense Mutation (SNP) | VAF 110/290 reads (38%) | catalogued as rs759354546, COSV52049572; called by muse, mutect2, varscan2
- DENND3 | c.2071G>T p.D691Y | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.51); catalogued as COSV52803389; called by muse, mutect2, varscan2
8,446 further variants in this file (5,760 protein-altering or splice-affecting, 1,595 silent, 1,091 other) are not listed here.
